Surgical pathology report (de-identified scan), TCGA case TCGA-DW-7834, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-7834-01A (Primary Tumor).

[page 1 of 8]
DIAGNOSIS:

1. Soft tissue, "psuedocapsule/lateral" (excision): Fibroadipose tissue, no tumor seen.
2. Soft tissue, "anterior perirenal fat" (excision): Adipose tissue, no tumor seen.
3. Soft tissue, "perirenal fat - upper pole" (excision): Adipose and fibrous tissue, no tumor seen.
4. Soft tissue, "scar tissue" (excision): Fibroadipose tissue, no tumor seen.
5. Kidney, left, "solid #1" (excision): Renal cell carcinoma, papillary type I.
6. Kidney, left, "solid #2" (excision): Renal cell carcinoma, papillary type I.
7. Kidney, left, "solid #3" (excision): Renal cell carcinoma, papillary type I.
8. Soft tissue, left perirenal, "scat tissue #4" (excision): Scar tissue and fibroadipose tissue, no tumor seen.
9. Kidney, left, "solid #5" (excision): Small focus of renal cell carcinoma, papillary type I.
10. Kidney, left "solid #6" (excision): Small focus of renal cell carcinoma, papillary type I.
11. Kidney, left "solid #7" (excision): Small focus of renal cell carcinoma, papillary type I.
12. Kidney, left "solid #8" (excision): Small focus of renal cell carcinoma, papillary type I.
13. Kidney, left "solid #9" (excision): Small focus of renal cell carcinoma, papillary type I.

Patient Identification

[page 2 of 8]
-
-
14. Kidney, left "solid #10" (excision): Renal cell carcinoma, papillary type I.
15. Kidney, left "solid #11" (excision): Benign kidney parenchyma with sclerotic glomeruli and inflammation, no tumor seen.
16. Kidney, left "solid #12" (excision): Renal cell carcinoma, papillary type I.
17. Kidney, left "upper pole cyst wall #13" (excision): Cystic lesion with irregular cuboidal lining, benign kidney parenchyma and fat, no tumor seen.
18. Kidney, left "solid #14" (excision): Renal cell carcinoma, papillary type I.
19. Kidney, left "solid #15" (excision): Renal cell carcinoma, papillary type I.
20. Kidney, left "solid #16" (excision): Renal cell carcinoma, papillary type I.
21. Kidney, left "solid #17" (excision): Small focus of renal cell carcinoma, papillary type I.
22. Kidney, left "solid #18" (excision): Small focus of renal cell carcinoma, papillary type I.
23. Kidney, left "solid #19" (excision): Small focus of renal cell carcinoma, papillary type I.
24. Kidney, left "normal tissue adjacent to #19" (excision): Benign kidney parenchyma with sclerotic glomeruli and inflammation, no tumor seen.
25. Kidney, left "#20" (excision): Renal cell carcinoma, papillary type I.
26. Kidney, left "solid #21" (excision): Small focus of renal cell carcinoma, papillary type I.
27. Soft tissue, left perirenal, "perirenal fat" (excision): Adipose tissue, no tumor seen.
28. Soft tissue, left perirenal, "perirenal fat lower pole" (excision): Adipose tissue, no tumor seen.
29. Skin, not otherwise specified (biopsy): Skin, no tumor seen.
30. Rib, left 11th (excision): Bony fragment consistent with rib, gross diagnosis only.

Patient Identification

[page 3 of 8]
CLINICAL INFORMATION: HISTORY:RENAL TUMORS * EXAM IS RELATED TO ORDERING PROTOCOL
Ordering Protocol: [REDACTED]

PROCEDURE: PREOP DX:#LEFT RENAL TUMORS POSTOP DX: SAME OPERATIVE FINDINGS: MULTIPLE
LEFT RENAL LESIONS

SPECIMENS SUBMITTED:

- 1) TUMOR, Pseudo capsule lateral (1FS)
- 2) FAT, Anterior perirenal (2FS)
- 3) FAT, Peri renal - upper pole (3FS)
- 4) SOFT TISSUE, NOS, Scar (4FS)
- 5) KIDNEY, Solid # 1
- 6) KIDNEY, Solid # 2
- 7) KIDNEY, Solid # 3
- 8) KIDNEY, Scar tissue
- 9) KIDNEY, Solid # 5
- 10) KIDNEY, Solid # 6
- 11) KIDNEY, Solid # 7
- 12) KIDNEY, Solid # 8
- 13) KIDNEY, Solid # 9
- 14) KIDNEY, Solid # 10
- 15) KIDNEY, Solid # 11
- 16) KIDNEY, Solid # 12
- 17) KIDNEY, Upper pole wall tumor # 13
- 18) KIDNEY, Solid # 14
- 19) KIDNEY, Solid # 15
- 20) KIDNEY, Solid # 16
- 21) KIDNEY, Solid # 17
- 22) KIDNEY, Solid # 18
- 23) KIDNEY, Solid # 19
- 24) KIDNEY, Normal tissue adjacent to # 19
- 25) KIDNEY, Solid # 20
- 26) KIDNEY, Solid # 21
- 27) FAT, Perirenal
- 28) FAT, Perirenal lower pole
- 29) SKIN BIOPSY
- 30) RIB, 11th left

INTRAOPERATIVE CONSULTATION

:

Patient Identification

[page 4 of 8]
Frozen Section Diagnosis 1FS: Benign fibrous tissue. (Diagnosis render [REDACTED].)

Frozen Section Diagnosis 2FS: Benign fibroadipose tissue. ([REDACTED].)

Frozen Section Diagnosis 3FS: Benign fibroadipose tissue ([REDACTED].)

Frozen Section Diagnosis 4FS: Benign fibrous tissue. ([REDACTED].)

GROSS DESCRIPTION:

1. Received fresh for frozen labeled with the patient's name, medical record number, and "pseudocapsule/lateral tumor" is a fragment of wispy red and tan, soft tissue measuring 1.2 x 1.2 x 0.3 cm., which is frozen in its entirety as 1FS1.
2. Received fresh for frozen section labeled with the patient's name, medical record number, and as "anterior peri-renal fat" consists of a yellow, light/tan fragment of soft tissue measuring 2.0 x 1.2 x 0.4 cm., which is frozen in its entirety as 2FS.
3. Received fresh for frozen section labeled with the patient's name, medical record number, and as "peri-renal fat - upper pole" consists of a single fragment of yellow fatty tissue, measuring 2.0 x 1.8 x 0.4 cm., which is frozen in its entirety as 3FS.
4. Received fresh for frozen section labeled with the patient's name, medical record number, and as "scar tissue" is a single tan/red fragment of soft tissue measuring 1.5 x 0.7 X 0.3 cm., which is frozen in its entirety as 4FS.
5. Received fresh in a single container labeled with the patient's name, medical record number, and "solid #1" is an off-white to tan nodule measuring 4 x 4 x 3 cm. Sectioning of the specimen demonstrates light tan to golden-yellow soft tissue. Portions of the specimen are procured by [REDACTED] lab. A representative portion of the specimen is forwarded to Surgical Pathology and is placed in a single cassette marked [REDACTED].
6. Received fresh in a container labeled with the patient's name, medical record number, and as "solid #2" is a single tan nodule measuring 0.7 x 0.7 x 0.5 cm. A portion of the specimen is procured by [REDACTED] lab. The remainder of the specimen is placed in a single cassette marked [REDACTED].
7. Received fresh in a single container labeled with the patient's name, medical record number, and as "solid #3" consists of two off-white fragments of soft tissue, measuring in aggregate 1.0 x 0.5 x 0.5 cm. Half of the specimen is procured by [REDACTED] lab. The remainder of the specimen is placed in its entirety in a single

Patient Identification

[page 5 of 8]
[REDACTED]

cassette marked [REDACTED] The specimen is placed in a biopsy bag before hand.

8. Received fresh in a single container labeled with the patient's name, medical record number, and as "scar tissue #4" are two red fragments of soft tissue measuring in aggregate 1.0 x 0.5 x 0.3 cm. The specimen is divided and portions are given to [REDACTED] lab. The remainder of the specimen is forwarded to Surgical Pathology is placed in its entirety in a single cassette marked [REDACTED]

9. Received fresh in a single container labeled with the patient's name, medical record number, and "solid #5" are two fragments of light tan soft tissue measuring in aggregate 0.9 x 0.6 x 0.4 cm., which are placed in their entirety in a single white cassette marked [REDACTED]

10. Received fresh in a single container labeled with the patient's name, medical record number, and as "solid #6" consists of a tan nodule of soft tissue measuring 1.5 x 1.0 x 1.0 cm. The specimen is sectioned to reveal red and gold soft tissue. Half of it is procured by [REDACTED] lab and the remainder of the specimen is placed in its entirety in a single cassette marked [REDACTED]

11. Received in a single formalin-filled container labeled with the patient's name, medical record number, and as "solid #7" consists of a single light tan fragment of soft tissue measuring 0.7 x 0.5 x 0.4 cm. , which is submitted in its entirety in a white cassette marked [REDACTED]

12. Received fresh in a single container labeled with the patient's name, medical record number, and as "solid #8" consists of two tan fragments of soft tissue measuring in aggregate 1.0 x 1.0 x 0.6 cm. Half of the specimen is procured by [REDACTED] lab. The remainder of the specimen is forwarded to Surgical Pathology is placed in a single cassette marked [REDACTED]

13. Received in a single formalin-filled container labeled with the patient's name, medical record number, and as "solid #9" is a single irregularly shaped fragment of light tan soft tissue measuring 1.2 x 0.5 x 0.5 cm., which is placed in its entirety in a single cassette marked [REDACTED]

14. Received in a single formalin-filled container labeled with the patient's name, medial record number, and "solid #10" are multiple fragments of light tan soft tissue measuring in aggregate 0.9 x 0.4 x 0.4 cm., which are filtered through a biopsy bag and submitted in their entirety in a single cassette marked [REDACTED]

15. Received in a single formalin-filled container labeled with the patient's name, medical record number, and as "solid #11" is a single irregularly shaped fragment of light tan soft tissue measuring 0.7 x 0.4 x 0.4 cm. which is placed in its entirety in a single cassette marked [REDACTED]

16. Received fresh in a single container labeled with the patient's name, medical record number, and as "solid #12" are multiple fragments of light tan soft tissue, measuring in aggregate 0.4 x 0.4 x 0.2 cm, which are

Patient Identification

[REDACTED]

[page 6 of 8]
[REDACTED]

wrapped in lens paper and submitted in entirety in a single cassette marked [REDACTED]

17. Received in a single formalin-filled container labeled with the patient's name, medical record number, and as "upper pole cyst wall #13" consists of light tan and fibrofatty soft tissue measuring in aggregate 2 x 1 x 0. cm., which are placed in their entirety in a single cassette marked [REDACTED]

18. Received in a single formalin-filled container labeled with the patient's name, medical record number, and as "solid #14" consists of multiple fragments of light tan and gold-colored soft tissue measuring in aggregate 1.2 x 0.8 x 0.4 cm., which are filtered through a biopsy bag and submitted in their entirety in a single cassette marked [REDACTED]

19. Received in a single formalin-filled container labeled with the patient's name, medical record number, and as "solid #15" is a single fragment of light tan soft tissue measuring 0.4 x 0.4 x 0.4 cm. which is wrapped in lens paper and submitted in its entirety in a single cassette marked [REDACTED]

20. Received fresh in a single container labeled with the patient's name, medical record number, and as "solid #16" is a gold/red fragment of soft tissue measuring 5 x 5 x 4.5 cm. It is sectioned to reveal yellow-gold tumor in a nodular morphology. Some of the tumor is soft with areas of hemorrhage. Portions of the tumor are procured by [REDACTED] lab. The specimen is then forwarded to Surgical Pathology. A representative portion of this specimen is placed in a single white cassette marked [REDACTED]

21. Received fresh in a single container labeled with the patient's name, medical record number, and as "solid #17" is a small tan nodule measuring 0.5 x 0.5 x 0.3 cm. A portion of the specimen is given to [REDACTED] lab. The remainder of the specimen is forwarded to Surgical Pathology is placed in its entirety in a single cassette marked [REDACTED]

22. Received fresh in a single container labeled with the patient's name, medical record number, and "solid #18" is a small light tan, soft tissue nodule measuring 0.5 x 0.5 x 0.5 cm. Half of the specimen is procured by [REDACTED] lab. The remainder of the specimen is forwarded to Surgical Pathology is placed in its entirety in a single white cassette marked [REDACTED]

23. Received fresh in a single container labeled with the patient's name, medical record number, and "solid #19" is a single light tan soft tissue nodule measuring 0.7 x 0.6 x 0.5 cm. One-half of the specimen is given to [REDACTED] lab. The remainder of the specimen is forwarded to Surgical Pathology is placed in its entirety in a single cassette marked [REDACTED]

24. Received in a single formalin-filled container labeled with the patient's name, medical record number, and as "normal tissue adjacent to #19" is a single nodular fragment of light tan soft tissue measuring 1 x 0.7 x 0.4 cm., which is placed in its entirety in a single cassette marked [REDACTED]

Patient Identification

[REDACTED]

[page 7 of 8]
25. Received fresh in a single container labeled with the patient's name, medical record number, and as "#20" is a single red/brown fragment of soft tissue in a nodular shape, measuring 0.7 x 0.6 x 0.6 cm. One-half of the specimen is given to [REDACTED] lab. The remainder of the specimen is forwarded to Surgical Pathology is placed in its entirety in a single cassette marked [REDACTED]

26. Received fresh in a single container labeled with the patient's name, medical record number, and as "solid #21" is a small light tan soft tissue fragment measuring 0.5 x 0.5 x 0.3 cm. One-half of the specimen is procured by [REDACTED] lab. The remainder of the tissue is forwarded to Surgical Pathology is placed in its entirety in a single cassette marked [REDACTED]

27. Received in a single formalin-filled container labeled with the patient's name, medical record number, and as "perirenal fat" is a single fragment of fibrofatty tissue measuring 4 x 1.5 x 0.5 cm. The specimen has areas of fibrosis along with fibrofatty tissue. The specimen is placed in its entirety in a single cassette marked [REDACTED]

28. Received in a single formalin-filled container labeled with the patient's name, medical record number, and as "perirenal fat lower pole" consists of multiple fragments of yellow fibroadipose tissue, measuring in aggregate 2.5 x 2 x 1.0 cm. The specimen is submitted in its entirety in toto in three cassettes marked [REDACTED]

29. Received in a saline in a single container labeled with the patient's name, medical record number, and as "skin biopsy" is an ellipse of skin measuring 2.2 X 1.0 x 0.7 cm. A fragment of the specimen is kept by Surgical Pathology and the remainder is given to [REDACTED] lab for fibroblastic culture. That portion forwarded to Surgical Pathology is placed in its entirety in a single cassette marked [REDACTED]

30. Received in a single formalin-filled container labeled with the patient's name, medical record number, and "11th rib - left" is a bony fragment in a shape consistent with segment of rib. It measures 6 cm. in greatest length. The proximal end measures 1.4 x 0.5 cm. and it tapers off to a cartilaginous end. There is a small amount of fibrous tissue and skeletal muscle associated with the specimen. This specimen is described for a gross diagnosis only.

Patient Identification

[page 8 of 8]
Patient Identification

1. Patient Name: [REDACTED]
2. Patient ID: [REDACTED]
3. Date of Birth: [REDACTED]

Source: NCI Genomic Data Commons file 20df317f-ee81-451d-9b63-81c09d122131 (TCGA-DW-7834.D2BBBA28-557A-4991-84A8-3F17303D3070.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).